Somatic mutation profile of tumor specimen TCGA-DX-A48V-01A (aliquot TCGA-DX-A48V-01A-11D-A307-09) from TCGA case TCGA-DX-A48V, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 78.7 years (28,754 days).
Specimen TCGA-DX-A48V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0f402bd-8e7f-45fd-ac89-0992357d8d4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A48V-10A (Blood Derived Normal), aliquot TCGA-DX-A48V-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de5d612a-e9ba-4a60-b271-cccb8a44bd5a

The open-access MAF lists 42 somatic variants for this specimen: 33 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 8, Splice Site 2, Translation Start Site 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.993+1G>T p.X331_splice | Splice Site (SNP) | VAF 87/93 reads (94%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2M | c.3310T>G p.Y1104D | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100588689; called by muse, mutect2, varscan2
- ACTR10 | c.1132T>C p.Y378H | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99581153; called by muse, mutect2
- AFM | c.1092C>G p.D364E | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99888842; called by muse, mutect2, varscan2
- AK5 | c.1180G>A p.E394K (on ENST00000354567 / NM_174858.3; = p.E368K on NM_012093.4) | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as COSV100642752; called by muse, mutect2, varscan2
- AK5 | c.1272G>C p.L424F (on ENST00000354567 / NM_174858.3; = p.L398F on NM_012093.4) | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as COSV100642753; called by muse, mutect2, varscan2
- AP5B1 | c.1861C>T p.H621Y | Missense Mutation (SNP) | VAF 86/181 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100376020; called by muse, mutect2, varscan2
- ATP6V1A | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 80/214 reads (37%) | SIFT tolerated (0.88); PolyPhen benign (0.017); catalogued as rs775322278, COSV99850143; called by muse, varscan2
- CACNA1S | c.2432T>G p.L811R | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100755016; called by muse, mutect2
- CAMKK1 | c.291C>A p.S97R | Missense Mutation (SNP) | VAF 92/111 reads (83%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV99340284; called by muse, mutect2, varscan2
- CCDC105 | c.381C>A p.H127Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99479910; called by muse, mutect2, varscan2
- CCDC3 | c.142G>C p.V48L | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV101121687; called by muse, mutect2
- CHAMP1 | c.1642C>G p.R548G | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV100778802, COSV63521992; called by muse, mutect2, varscan2
- COL12A1 | c.5035G>A p.A1679T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs550455854, COSV100486016; called by muse, mutect2, varscan2
- DISP3 | c.3880G>A p.V1294I | Missense Mutation (SNP) | VAF 87/98 reads (89%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.686); catalogued as rs775248733, COSV53823292; called by muse, mutect2, varscan2
- GCLC | c.13C>G p.P5A (on ENST00000643939; = p.P9A on NM_001498.4) | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV99988652; called by muse, mutect2, varscan2
- KIAA1549 | c.2195C>T p.A732V | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs375118283; called by muse, mutect2, varscan2
- MAGEB2 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 79/87 reads (91%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as COSV66781308; called by muse, mutect2, varscan2
- PCDHB11 | c.649G>T p.G217C | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99503958, COSV99504345; called by muse, mutect2, varscan2
- PCF11 | c.1790G>T p.W597L | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100018418, COSV53534317; called by muse, mutect2, varscan2
- PPAT | c.15G>T p.E5D | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV99947271; called by muse, mutect2, varscan2
- PRODH2 | c.1249C>A p.L417M (on ENST00000301175; = p.L341M on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT tolerated (0.17); PolyPhen benign (0.136); catalogued as rs1005736729, COSV99995325; called by muse, varscan2
- PTPRM | c.3875C>T p.A1292V | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100157409; called by muse, mutect2, varscan2
- PTPRM | c.3877C>T p.Q1293* | Nonsense Mutation (SNP) | VAF 38/104 reads (37%) | catalogued as COSV59870662; called by muse, mutect2, varscan2
- SLC45A4 | c.2221G>T p.G741C (on ENST00000517878 / NM_001286646.2; = p.G690C on NM_001080431.2) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV99198316; called by muse, mutect2, varscan2
- SPEG | c.2669T>G p.I890S | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV100404544; called by muse, mutect2, varscan2
- STIM2 | c.1231C>T p.H411Y | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs927372951, COSV52840690, COSV99402671; called by muse, mutect2, varscan2
- TIE1 | c.2720G>A p.C907Y | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754542928, COSV100992081; called by muse, mutect2, varscan2
- TPTE | c.356A>C p.K119T (on ENST00000618007 / NM_199261.4; = p.K101T on NM_199259.4) | Missense Mutation (SNP) | VAF 105/1028 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as rs746988740; called by muse, mutect2, varscan2
- TRPV2 | c.1207T>C p.F403L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV58428166; called by muse, mutect2
- FCGBP | c.5350G>A p.V1784M | Missense Mutation (SNP) | VAF 89/100 reads (89%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- GNAT1 | c.-3_12del | Translation Start Site (DEL) | VAF 40/96 reads (42%) | called by mutect2, pindel, varscan2
- TLK2 | c.709_720+28del p.X237_splice | Splice Site (DEL) | VAF 18/84 reads (21%) | called by mutect2, pindel
- ASTN2 | c.936C>T p.D312= | Silent (SNP) | VAF 51/123 reads (41%) | catalogued as rs757483065, COSV100527592, COSV57792384; called by muse, mutect2, varscan2
- CCDC134 | c.157C>T p.L53= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as COSV99740711; called by muse, mutect2, varscan2
- CDH7 | c.1938C>T p.I646= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV100542406; called by muse, mutect2, varscan2
- LRRC56 | c.1458G>A p.G486= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs1156802670, COSV99530129; called by muse, mutect2, varscan2
- OBSCN | c.15969C>T p.V5323= | Silent (SNP) | VAF 53/123 reads (43%) | catalogued as rs1233596683, COSV52770856, COSV99478414; called by muse, mutect2, varscan2
- OPLAH | c.2169C>T p.A723= | Silent (SNP) | VAF 53/119 reads (45%) | catalogued as rs782379470, COSV101470773; called by muse, mutect2, varscan2
- PLXNB1 | c.975C>G p.P325= | Silent (SNP) | VAF 50/114 reads (44%) | catalogued as COSV99602862; called by muse, mutect2, varscan2
- SIPA1L1 | c.2973C>T p.G991= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as COSV100665573; called by muse, mutect2
- AP000769.3 | chr11:65505361 G>C | 5'Flank (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
